Somatic mutation profile of tumor specimen MMRF_1927_1_PB_CD138pos (aliquot MMRF_1927_1_PB_CD138pos_T1_KBS5U_L06414) from MMRF case MMRF_1927, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.0 years (24,477 days).
Specimen MMRF_1927_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da573b2b-f564-411e-88e9-78ae343c3c69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1927_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1927_1_PB_CD3pos_C5_KBS5U_L06459; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b6fa322-ccb1-4158-972c-c0359980290f

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 4, Missense Mutation 4, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.2656_2657insT p.P886Lfs*4 | Frame Shift Ins (INS) | VAF 30/78 reads (38%) | called by mutect2, varscan2
- C1S | c.1403A>G p.Y468C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- CACNA2D1 | c.1537T>G p.F513V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- POLE3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SGCZ | c.767T>G p.I256S | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, varscan2
- NFIB | c.*1078C>T | 3'UTR (SNP) | VAF 11/21 reads (52%) | catalogued as rs1454982667; called by muse, mutect2, varscan2
- PAK2 | c.*1446A>G | 3'UTR (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- PAWR | c.*3623T>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- TFAP2E | c.*331G>A | 3'UTR (SNP) | VAF 3/47 reads (6%) | catalogued as rs907030343, COSV64697298; called by muse, mutect2
- ZNF720 | c.361+1961dup | Intron (INS) | VAF 4/13 reads (31%) | called by mutect2, varscan2
